Gene-level copy-number profile of tumor specimen ALCH-B6UY-TTP1-A from ALCHEMIST case ALCH-B6UY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,410 days).
Specimen ALCH-B6UY-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cdedc47c-0f16-433c-bc29-0c0b12863b80.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6UY-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/a71359d2-42b1-4ec4-bdfe-f69e695eed55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 18,412; copy number 2: 36,246; copy number 3: 4,175; copy number 4: 67; copy number 5: 7; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:102,803,929–102,804,031, 1 gene (within-gene range 0–2): RNU6-1231P.
- chr22:20,652,730–20,698,938, 4 genes (within-gene range 0–1): SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:571,277–583,493, 1 gene, copy number 5 (within-gene range 3–5): BSG.
- chr19:55,379,244–55,384,292, 1 gene, copy number 5: TMEM238.
- chr20:63,738,270–63,744,050, 2 genes, copy number 5 (within-gene range 1–5): AL121845.2, SLC2A4RG.
- chr22:18,615,581–18,625,289, 2 genes, copy number 5: Metazoa_SRP, SUSD2P2.
- chr22:18,715,815–18,757,906, 2 genes, copy number 5–8: PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 15,578. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
